Somatic mutation profile of tumor specimen MP2PRT-PARUAT-TMP1-A (aliquot MP2PRT-PARUAT-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PARUAT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (912 days).
Specimen MP2PRT-PARUAT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be6e6946-58a5-4971-a04a-abf4d4a55136.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUAT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUAT-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/512a9421-ac83-43d2-bfe7-f2ccdb1ec4d1

The open-access MAF lists 20 somatic variants for this specimen: 10 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 8, Splice Region 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACBD3 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.885); catalogued as rs767804126, COSV64730401, COSV64730977; called by muse, mutect2, varscan2
- COL11A1 | c.1791G>A p.K597= | Splice Region (SNP) | VAF 39/122 reads (32%) | catalogued as CS1411323; called by muse, mutect2, varscan2
- FRMPD2 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100564070, COSV59716754; called by muse, mutect2, varscan2
- HS3ST2 | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 322/734 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs564701428, COSV54457820; called by muse, mutect2, varscan2
- KRT82 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 95/952 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs768909606; called by muse, mutect2
- OXCT2 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 206/746 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs377118062; called by muse, mutect2, varscan2
- PAX4 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 139/484 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs1230981557; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406868 CCATTCACAGTGTTACAAGCCATAACAAAA>GG | Missense Mutation (DEL) | VAF 42/163 reads (26%) | called by pindel, varscan2*
- MIPOL1 | c.870G>T p.Q290H | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TPM3 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- AGAP2 | c.1005C>T p.G335= | Silent (SNP) | VAF 368/856 reads (43%) | catalogued as rs755399225, COSV57727116, COSV99222411; called by muse, mutect2, varscan2
- CGREF1 | c.189G>A p.V63= | Silent (SNP) | VAF 219/501 reads (44%) | catalogued as rs546668139; called by muse, mutect2, varscan2
- DRD2 | c.432G>A p.T144= | Silent (SNP) | VAF 186/524 reads (35%) | catalogued as rs201471837, COSV60758769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNC2H1 | c.168C>A p.S56= | Silent (SNP) | VAF 33/376 reads (9%) | catalogued as COSV62086306; called by muse, mutect2
- MAGEA12 | c.834C>T p.L278= | Silent (SNP) | VAF 154/460 reads (33%) | catalogued as COSV63294798; called by muse, mutect2, varscan2
- PCDHA9 | c.1752G>A p.S584= | Silent (SNP) | VAF 484/552 reads (88%) | catalogued as rs782099893, COSV100968930; called by muse, mutect2, varscan2
- SLC24A5 | c.312G>A p.L104= | Silent (SNP) | VAF 49/146 reads (34%) | called by muse, mutect2, varscan2
- VPS8 | c.2970G>A p.T990= (on ENST00000625842 / NM_001349294.1; = p.T988= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as rs761329831; called by muse, mutect2, varscan2
- PLEKHG4B | chr5:140093 A>T | 5'Flank (SNP) | VAF 275/664 reads (41%) | called by muse, mutect2, varscan2
- STOX1 | c.310+188_310+208del | Intron (DEL) | VAF 38/48 reads (79%) | catalogued as rs1376716212; called by mutect2, varscan2
